Somatic mutation profile of tumor specimen C3N-00297-01 (aliquot CPT0011130011) from CPTAC case C3N-00297, project CPTAC-3 (Larynx — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 69.1 years (25,254 days).
Specimen C3N-00297-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Larynx; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b7441e1e-c9af-48f5-929f-9a39da9560ee.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00297-31 (Blood Derived Normal), aliquot CPT0011220002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4d584cf1-b2d2-4f11-9d9c-fb843e03a0aa

The open-access MAF lists 141 somatic variants for this specimen: 99 protein-altering or splice-affecting, 27 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 80, Silent 27, Nonsense Mutation 7, Intron 7, Frame Shift Del 4, 5'UTR 3, Splice Region 3, In Frame Del 2, Splice Site 2, RNA 2, 5'Flank 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.358G>T p.E120* | Nonsense Mutation (SNP) | VAF 238/534 reads (45%) | hotspot (GDC flag); catalogued as CD972119, COSV58683444, COSV58717600; called by muse, mutect2, varscan2
- ABCC2 | c.2729G>A p.R910H | Missense Mutation (SNP) | VAF 131/679 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs149359610; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADAM12 | c.2480G>A p.R827H | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.579); catalogued as rs767535609; called by muse, mutect2, varscan2
- ADGRB2 | c.3292G>A p.V1098I | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs149102471; called by muse, mutect2, varscan2
- AHNAK | c.9586G>A p.E3196K | Missense Mutation (SNP) | VAF 62/365 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.984); catalogued as COSV57224492; called by muse, mutect2, varscan2
- ANO2 | c.2758G>T p.V920L (on ENST00000356134 / NM_001278597.3; = p.V924L on NM_001278596.3) | Missense Mutation (SNP) | VAF 79/219 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.405); catalogued as rs376930143; called by muse, mutect2, varscan2
- ANO4 | c.1021C>T p.R341W (on ENST00000392977 / NM_001286615.2; = p.R306W on NM_178826.4) | Missense Mutation (SNP) | VAF 20/129 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs771044930; called by muse, mutect2, varscan2
- ARL2BP | c.403C>T p.R135* | Nonsense Mutation (SNP) | VAF 39/197 reads (20%) | catalogued as rs754132288; called by muse, mutect2, varscan2
- ASCL1 | c.301C>T p.R101C | Missense Mutation (SNP) | VAF 50/330 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57151569; called by muse, mutect2, varscan2
- B3GALNT2 | c.185A>G p.N62S | Missense Mutation (SNP) | VAF 28/186 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs775311855; called by muse, mutect2, varscan2
- C1orf43 | c.191T>C p.I64T (on ENST00000368521 / NM_001297718.2; = p.I30T on NM_015449.4) | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs148001096; called by muse, mutect2, varscan2
- CARD11 | c.2768C>T p.S923L | Missense Mutation (SNP) | VAF 35/282 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.079); catalogued as rs371300769; called by muse, mutect2, varscan2
- CD7 | c.647C>T p.S216L | Missense Mutation (SNP) | VAF 56/244 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.296); catalogued as rs779224116, COSV100444879; called by muse, mutect2, varscan2
- CHD7 | c.2552G>T p.R851I | Missense Mutation (SNP) | VAF 23/122 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as COSV71107551, COSV71111239; called by muse, mutect2, varscan2
- COL25A1 | c.916G>A p.G306R | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67657914; called by muse, mutect2
- CPLX2 | c.160C>T p.R54C | Missense Mutation (SNP) | VAF 40/247 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as rs565316889; called by muse, mutect2, varscan2
- DDX42 | c.898G>A p.G300S | Missense Mutation (SNP) | VAF 39/163 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63791281; called by muse, mutect2, varscan2
- FUS | c.776G>A p.R259H | Missense Mutation (SNP) | VAF 45/316 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as rs1340617413, COSV54218814; called by muse, mutect2, varscan2
- FUT1 | c.988del p.L330Cfs*7 | Frame Shift Del (DEL) | VAF 32/268 reads (12%) | catalogued as COSV59567570; called by mutect2, pindel
- HIVEP2 | c.1025C>G p.S342C | Missense Mutation (SNP) | VAF 43/268 reads (16%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.707); catalogued as COSV50011372; called by muse, mutect2, varscan2
- HOXD1 | c.97C>T p.R33W | Missense Mutation (SNP) | VAF 77/309 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.152); catalogued as rs1412453358, COSV100514063; called by muse, mutect2, varscan2
- IGHG4 | c.919G>T p.V307L | Missense Mutation (SNP) | VAF 90/482 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs376514771; called by muse, mutect2, varscan2
- IQCA1 | c.829G>A p.A277T | Missense Mutation (SNP) | VAF 46/349 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.688); catalogued as rs1364050704, COSV54509923; called by muse, mutect2, varscan2
- KCNG2 | c.170G>A p.R57H | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.108); catalogued as COSV60269003; called by muse, mutect2, varscan2
- KIAA1614 | c.3131G>A p.R1044K | Missense Mutation (SNP) | VAF 36/182 reads (20%) | SIFT tolerated (0.62); PolyPhen benign (0.048); catalogued as COSV100799727; called by muse, mutect2, varscan2
- MAP6 | c.1238C>T p.A413V | Missense Mutation (SNP) | VAF 110/558 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs199501525; called by muse, mutect2, varscan2
- NAV3 | c.2614G>A p.D872N | Missense Mutation (SNP) | VAF 43/229 reads (19%) | SIFT tolerated (0.5); PolyPhen benign (0.335); catalogued as rs751418701, COSV57059561, COSV57075480; called by muse, mutect2, varscan2
- NOTCH4 | c.5378G>T p.R1793L | Missense Mutation (SNP) | VAF 28/147 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.072); catalogued as COSV66679301, COSV66683180; called by muse, mutect2, varscan2
- OR2L8 | c.714G>T p.L238F | Missense Mutation (SNP) | VAF 30/154 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV61728227; called by muse, varscan2
- PCDHGA10 | c.1831C>T p.R611C | Missense Mutation (SNP) | VAF 128/603 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.16); catalogued as rs1353721901, COSV53909531; called by muse, mutect2, varscan2
- POMGNT1 | c.508G>A p.G170S | Missense Mutation (SNP) | VAF 125/493 reads (25%) | PolyPhen probably damaging (0.979); catalogued as rs1164265990, COSV100915853, COSV64340898; called by muse, mutect2, varscan2
- PRMT1 | c.214C>G p.R72G | Missense Mutation (SNP) | VAF 22/148 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as COSV101212268; called by muse, mutect2
- SEMA6A | c.2213C>T p.T738M | Missense Mutation (SNP) | VAF 55/294 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs368558091; called by muse, mutect2, varscan2
- SLC5A4 | c.1871G>C p.S624T | Missense Mutation (SNP) | VAF 97/460 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.028); catalogued as COSV56668569; called by muse, mutect2, varscan2
- TNIP2 | c.1184C>T p.A395V | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs144696558; called by muse, mutect2, varscan2
- TRIB2 | c.881C>G p.S294* | Nonsense Mutation (SNP) | VAF 101/490 reads (21%) | catalogued as COSV50229597; called by muse, mutect2, varscan2
- UNC13C | c.5053T>C p.Y1685H | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV99523450; called by muse, mutect2, varscan2
- ZNF25 | c.887C>T p.S296F | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.027); catalogued as COSV56922226; called by muse, mutect2, varscan2
- ZNF34 | c.1144C>A p.R382S | Missense Mutation (SNP) | VAF 56/316 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.191); catalogued as rs750323793, COSV58638606; called by muse, mutect2, varscan2
- ABCC6 | c.439C>G p.P147A | Missense Mutation (SNP) | VAF 80/463 reads (17%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.577); called by muse, mutect2, varscan2
- AHNAK2 | c.6698_6699del p.K2233Rfs*43 | Frame Shift Del (DEL) | VAF 124/665 reads (19%) | called by mutect2, pindel, varscan2
- ARMC3 | c.952G>C p.E318Q | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ASAP2 | c.582C>A p.F194L | Missense Mutation (SNP) | VAF 41/187 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- CCDC58 | c.325-30_333del p.X109_splice | Splice Site (DEL) | VAF 7/86 reads (8%) | called by mutect2, pindel
- CFAP46 | c.7646G>C p.R2549P | Missense Mutation (SNP) | VAF 43/216 reads (20%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CHD4 | c.1528C>G p.P510A (on ENST00000357008 / NM_001363606.2; = p.P523A on NM_001273.5) | Missense Mutation (SNP) | VAF 21/160 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- CILP | c.1990T>A p.F664I | Missense Mutation (SNP) | VAF 69/331 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CILP | c.1989C>A p.D663E | Missense Mutation (SNP) | VAF 69/328 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CNR1 | c.55G>A p.D19N | Missense Mutation (SNP) | VAF 26/113 reads (23%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- COG3 | c.1706A>G p.Y569C | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); called by muse, mutect2
- COL20A1 | c.3148G>A p.A1050T | Missense Mutation (SNP) | VAF 45/265 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.215); called by muse, mutect2, varscan2
- COL6A3 | c.301G>C p.E101Q | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- CSTB | c.66+2T>G p.X22_splice | Splice Site (SNP) | VAF 96/596 reads (16%) | called by muse, mutect2, varscan2
- CTDSPL2 | c.840G>T p.L280F | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.354); called by muse, mutect2, varscan2
- CTNNA2 | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT tolerated (0.51); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- DNMBP | c.3972G>T p.Q1324H | Missense Mutation (SNP) | VAF 57/227 reads (25%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.664); called by muse, mutect2, varscan2
- EFL1 | c.268C>G p.L90V | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.571); called by muse, mutect2, varscan2
- FICD | c.478G>C p.D160H | Missense Mutation (SNP) | VAF 66/275 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- FOXB2 | c.881T>C p.V294A | Missense Mutation (SNP) | VAF 57/420 reads (14%) | SIFT tolerated, low confidence (0.27); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- FOXD4L4 | c.448C>T p.P150S | Missense Mutation (SNP) | VAF 28/203 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- FRAS1 | c.11703G>T p.Q3901H | Missense Mutation (SNP) | VAF 27/142 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- FUT1 | c.815_827del p.I272Rfs*4 | Frame Shift Del (DEL) | VAF 68/613 reads (11%) | called by mutect2, pindel
- GAL3ST1 | c.906G>T p.M302I | Missense Mutation (SNP) | VAF 33/141 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- HMCN1 | c.7965G>C p.M2655I | Missense Mutation (SNP) | VAF 56/275 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- HS6ST1 | c.889_912del p.Q297_F304del | In Frame Del (DEL) | VAF 160/998 reads (16%) | called by mutect2, pindel
- INTS10 | c.1685C>T p.P562L | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- ITIH3 | c.2363_2365del p.H788del | In Frame Del (DEL) | VAF 31/198 reads (16%) | called by mutect2, pindel, varscan2
- LRP2 | c.3075G>T p.Q1025H | Missense Mutation (SNP) | VAF 80/387 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- MAGEL2 | c.1209G>A p.W403* | Nonsense Mutation (SNP) | VAF 12/48 reads (25%) | called by muse, mutect2, varscan2
- MAP3K14 | c.779A>C p.Y260S | Missense Mutation (SNP) | VAF 53/256 reads (21%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.282); called by muse, mutect2, varscan2
- MBD6 | c.2275_2278dup p.S760Tfs*34 | Frame Shift Ins (INS) | VAF 24/204 reads (12%) | called by mutect2, pindel
- MYO1C | c.1507G>A p.E503K (on ENST00000648651 / NM_001080779.2; = p.E468K on NM_033375.5) | Missense Mutation (SNP) | VAF 71/286 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- MYO1C | c.1068G>C p.R356S (on ENST00000648651 / NM_001080779.2; = p.R321S on NM_033375.5) | Missense Mutation (SNP) | VAF 81/378 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.367); called by muse, mutect2, varscan2
- OR1Q1 | c.563C>G p.S188C | Missense Mutation (SNP) | VAF 40/205 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, varscan2
- OR2AJ1 | c.504C>A p.F168L | Missense Mutation (SNP) | VAF 46/189 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.565); called by muse, mutect2, varscan2
- PCDHB10 | c.1024G>C p.D342H | Missense Mutation (SNP) | VAF 44/205 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PDE1C | c.377G>T p.R126L | Missense Mutation (SNP) | VAF 44/196 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); called by muse, mutect2, varscan2
- PIGB | c.638C>A p.S213* | Nonsense Mutation (SNP) | VAF 7/39 reads (18%) | called by muse, mutect2, varscan2
- PLCE1 | c.397G>C p.D133H | Missense Mutation (SNP) | VAF 55/227 reads (24%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLEC | c.8302G>A p.D2768N (on ENST00000322810 / NM_201380.4; = p.D2658N on NM_000445.5) | Missense Mutation (SNP) | VAF 154/911 reads (17%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PLEKHH2 | c.3350A>G p.H1117R | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PPP4R3C | c.1944A>T p.K648N | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- QARS1 | c.266-8C>G | Splice Region (SNP) | VAF 106/394 reads (27%) | called by muse, mutect2, varscan2
- QARS1 | c.115C>G p.Q39E | Missense Mutation (SNP) | VAF 38/117 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- RBMS1 | c.358G>T p.V120L | Missense Mutation (SNP) | VAF 26/159 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- RGS7BP | c.168T>A p.L56= | Splice Region (SNP) | VAF 24/115 reads (21%) | called by muse, varscan2
- RGS7BP | c.203G>A p.R68Q | Missense Mutation (SNP) | VAF 30/170 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, varscan2
- SACS | c.8307C>G p.I2769M | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- SLC22A17 | n.1551G>C | Splice Region (SNP) | VAF 24/107 reads (22%) | called by muse, mutect2, varscan2
- TANC2 | c.200C>T p.P67L | Missense Mutation (SNP) | VAF 43/253 reads (17%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- TBATA | c.673C>T p.Q225* | Nonsense Mutation (SNP) | VAF 26/127 reads (20%) | called by muse, mutect2, varscan2
- TBC1D12 | c.178G>T p.E60* | Nonsense Mutation (SNP) | VAF 37/189 reads (20%) | called by muse, mutect2, varscan2
- TJP2 | c.1408G>C p.V470L | Missense Mutation (SNP) | VAF 86/439 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TONSL | c.1245G>C p.Q415H | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- TTC22 | c.1534C>T p.R512C | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- TTC39A | c.600G>T p.E200D (on ENST00000447632 / NM_001297665.1; = p.E165D on NM_001080494.3) | Missense Mutation (SNP) | VAF 35/209 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- VAX1 | c.75_76del p.H26Qfs*32 | Frame Shift Del (DEL) | VAF 76/445 reads (17%) | called by pindel, varscan2
- ZNF331 | c.938A>G p.Y313C | Missense Mutation (SNP) | VAF 49/207 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- ZNF341 | c.1300G>A p.E434K (on ENST00000375200 / NM_001282935.1; = p.E427K on NM_032819.4) | Missense Mutation (SNP) | VAF 32/163 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- ANK2 | c.11709C>T p.I3903= | Silent (SNP) | VAF 33/250 reads (13%) | catalogued as COSV52147931; called by muse, mutect2, varscan2
- CA8 | c.585C>A p.S195= | Silent (SNP) | VAF 21/112 reads (19%) | called by muse, mutect2, varscan2
- CDH23 | c.9444T>C p.H3148= | Silent (SNP) | VAF 87/440 reads (20%) | catalogued as rs776395158; called by muse, mutect2, varscan2
- COL8A2 | c.216G>T p.P72= | Silent (SNP) | VAF 39/253 reads (15%) | catalogued as COSV57441642; called by muse, mutect2, varscan2
- DENND2A | c.2133C>T p.G711= | Silent (SNP) | VAF 39/182 reads (21%) | called by muse, mutect2, varscan2
- FCRL3 | c.1647C>T p.G549= | Silent (SNP) | VAF 32/185 reads (17%) | catalogued as rs1490214671; called by muse, mutect2, varscan2
- FUT1 | c.40C>T p.L14= | Silent (SNP) | VAF 88/597 reads (15%) | catalogued as rs1214847001; called by muse, mutect2, varscan2
- GART | c.736C>T p.L246= | Silent (SNP) | VAF 18/133 reads (14%) | catalogued as rs201437866, COSV63114432; called by muse, mutect2, varscan2
- GPX4 | c.195C>A p.I65= | Silent (SNP) | VAF 37/119 reads (31%) | called by muse, mutect2, varscan2
- HIP1 | c.2340G>A p.G780= | Silent (SNP) | VAF 60/306 reads (20%) | called by muse, mutect2, varscan2
- HIP1 | c.402G>T p.G134= | Silent (SNP) | VAF 73/402 reads (18%) | catalogued as rs782307891; called by muse, mutect2, varscan2
- KLHL34 | c.36C>T p.G12= | Silent (SNP) | VAF 17/52 reads (33%) | catalogued as rs745719849, COSV65280338; called by muse, mutect2, varscan2
- NCKAP5L | c.2766C>T p.G922= | Silent (SNP) | VAF 53/271 reads (20%) | called by muse, mutect2, varscan2
- NLRP5 | c.30A>T p.G10= | Silent (SNP) | VAF 36/184 reads (20%) | called by muse, mutect2, varscan2
- NSL1 | c.138G>A p.V46= | Silent (SNP) | VAF 48/321 reads (15%) | called by muse, mutect2, varscan2
- OR1Q1 | c.621C>T p.I207= | Silent (SNP) | VAF 54/296 reads (18%) | catalogued as COSV99939194; called by muse, varscan2
- PCDHGA3 | c.2055C>T p.N685= | Silent (SNP) | VAF 130/546 reads (24%) | called by muse, mutect2, varscan2
- PDE3A | c.1062C>T p.H354= | Silent (SNP) | VAF 90/352 reads (26%) | catalogued as rs773971834, COSV100762467; called by muse, mutect2, varscan2
- PDGFRA | c.1464G>A p.V488= | Silent (SNP) | VAF 79/337 reads (23%) | called by muse, mutect2, varscan2
- PGAP6 | c.834G>A p.L278= | Silent (SNP) | VAF 17/98 reads (17%) | called by muse, mutect2, varscan2
- POLG | c.1455C>G p.L485= | Silent (SNP) | VAF 142/711 reads (20%) | called by muse, mutect2, varscan2
- TARM1 | c.730C>A p.R244= (on ENST00000616041 / NM_001330650.1; = p.R236= on NM_001135686.3) | Silent (SNP) | VAF 26/243 reads (11%) | catalogued as COSV101444633; called by muse, mutect2
- TM9SF4 | c.1230G>A p.K410= | Silent (SNP) | VAF 68/366 reads (19%) | catalogued as COSV54104610; called by muse, mutect2, varscan2
- UACA | c.3483C>T p.N1161= | Silent (SNP) | VAF 20/134 reads (15%) | catalogued as rs767439854; called by muse, mutect2, varscan2
- UGT2B28 | c.327T>C p.F109= | Silent (SNP) | VAF 11/72 reads (15%) | called by muse, mutect2, varscan2
- ZNF23 | c.1623C>T p.F541= | Silent (SNP) | VAF 19/126 reads (15%) | called by muse, mutect2, varscan2
- ZNF629 | c.114A>G p.E38= | Silent (SNP) | VAF 81/475 reads (17%) | called by muse, mutect2, varscan2
- AC138749.1 | n.530A>T | RNA (SNP) | VAF 23/544 reads (4%) | called by muse, mutect2
- AF186192.2 | n.71-958G>T | Intron (SNP) | VAF 113/579 reads (20%) | called by muse, mutect2, varscan2
- AL049777.1 | n.510+4707G>C | Intron (SNP) | VAF 30/191 reads (16%) | catalogued as rs775304025; called by muse, varscan2
- ARL2 | c.339+115C>G | Intron (SNP) | VAF 141/578 reads (24%) | catalogued as rs1271110058; called by muse, mutect2, varscan2
- C8orf34-AS1 | n.565C>A | RNA (SNP) | VAF 14/94 reads (15%) | called by muse, mutect2, varscan2
- CHD8 | c.5182+12G>C | Intron (SNP) | VAF 24/115 reads (21%) | called by muse, mutect2, varscan2
- GRIK4 | c.907-2246G>A | Intron (SNP) | VAF 33/132 reads (25%) | called by muse, mutect2, varscan2
- KLHL1 | c.*19G>A | 3'UTR (SNP) | VAF 18/79 reads (23%) | called by muse, mutect2, varscan2
- MYLK | c.1942+11G>T | Intron (SNP) | VAF 69/408 reads (17%) | called by muse, mutect2, varscan2
- PDX1 | c.-45_-42delinsC | 5'UTR (DEL) | VAF 50/270 reads (19%) | called by pindel, varscan2*
- POLR1A | c.-4G>C | 5'UTR (SNP) | VAF 45/205 reads (22%) | called by muse, mutect2, varscan2
- QARS1 | c.266-100C>A | Intron (SNP) | VAF 46/162 reads (28%) | called by muse, mutect2, varscan2
- RNU1-6P | chr1:16536037 G>C | 5'Flank (SNP) | VAF 55/1273 reads (4%) | called by muse, mutect2
- RNU6-713P | chr12:40550136 C>A | 3'Flank (SNP) | VAF 16/119 reads (13%) | called by muse, mutect2
- TBXAS1 | c.-75C>T | 5'UTR (SNP) | VAF 123/539 reads (23%) | catalogued as rs780793497; called by muse, mutect2, varscan2
